CPTAC case C3L-02891 — Bronchus and lung — Squamous Cell Neoplasms (CPTAC-3)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of the Clinical Proteomic Tumor Analysis Consortium (CPTAC). Disease type: Squamous Cell Neoplasms; Primary site: Bronchus and lung. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/a7ac541e-35c7-41a2-ba31-1d7a6b22e0ae

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino; Year of birth: 1951; Vital status: Alive; Country of birth: United States.

Diagnoses (1)
1. Squamous cell carcinoma, NOS: ICD-O-3 morphology code: 8070/3; Tissue or organ of origin: Lung, NOS; Site of resection or biopsy: Lung, NOS; Age at diagnosis: 66.5 years (24,282 days); Year of diagnosis: 2018; AJCC staging edition: 8th; AJCC pathologic T: T1c; AJCC pathologic N: N1; AJCC pathologic M: M0; AJCC pathologic stage: Stage IIB; Tumor grade: G3; Residual disease: RX; Last known disease status: Tumor free; Days to last known disease status: 1,707 days (4.7 years); Progression or recurrence: no; Days to last follow up: 1,707 days (4.7 years); Tumor focality: Unifocal.
   Pathology details: Greatest tumor dimension: 2.7 cm (a second GDC size field records 4.5 cm); Lymph node involvement: Positive; Lymph nodes positive: 5; Lymph nodes tested: 15; Margin status: Involved.
   Chemotherapy — whether it was given is not recorded by GDC; Treatment outcome: Complete Response.
   Radiation Therapy, NOS — whether it was given is not recorded by GDC; Treatment outcome: Complete Response.

Follow-up (6 entries)
- Days to follow up: 333 days; Disease response: Tumor Free.
- Days to follow up: 690 days (1.9 years); Disease response: Tumor Free.
- Days to follow up: 1,074 days (2.9 years); Disease response: Complete Response.
- Days to follow up: 1,074 days (2.9 years); Disease response: Tumor Free.
- Days to follow up: 1,412 days (3.9 years); Disease response: Tumor Free.
- Days to follow up: 1,707 days (4.7 years); Disease response: Tumor Free.

Other clinical attributes
- Weight: 56.7 kg; Height: 157.48 cm; BMI: 22.86; DLCO (% of predicted): 42; FEV1/FVC after bronchodilator (%): 62; FEV1/FVC before bronchodilator (%): 65; FEV1 after bronchodilator (% of reference): 95; FEV1 before bronchodilator (% of reference): 77.

Exposures
- Tobacco smoking status: Current Reformed Smoker for < or = 15 yrs; Cigarettes per day: 40; Tobacco smoking quit year: 2003; Alcohol history: No; Alcohol intensity: Lifelong Non-Drinker.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample C3L-02891-03: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Lung; Biospecimen laterality: Left; Preservation method: Snap Frozen; Freezing method: LN2; Days to sample procurement: 0 days; Initial weight: 215 mg; Time between excision and freezing: 23 minutes; Method of sample procurement: Tumor Resection; Diagnosis pathologically confirmed: Yes.
  Slide C3L-02891-23: Section location: Base of upper lobe base/superior lower lobe; Percent tumor nuclei: 65; Percent necrosis: 5.
- Sample C3L-02891-06: Sample type: Solid Tissue Normal; Tissue type: Normal; Specimen type: Solid Tissue; Biospecimen anatomic site: Lung; Biospecimen laterality: Left; Preservation method: Snap Frozen; Freezing method: LN2; Days to sample procurement: 0 days; Initial weight: 200 mg; Time between excision and freezing: 23 minutes; Method of sample procurement: Surgical Resection; Diagnosis pathologically confirmed: Yes.
- Sample C3L-02891-31: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood Components NOS; Biospecimen anatomic site: Blood; Preservation method: Frozen; Freezing method: -20 (unit not recorded by GDC); Days to sample procurement: 0 days; Method of sample procurement: Blood Draw.
